Somatic mutation profile of tumor specimen HCM-SANG-0267-D12-86A (aliquot HCM-SANG-0267-D12-86A-01D-A85C-36) from HCMI case HCM-SANG-0267-D12, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-SANG-0267-D12-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3749b7b5-25bd-4365-8b57-bfef934ab586.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0267-D12-10A (Blood Derived Normal), aliquot HCM-SANG-0267-D12-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db575102-851f-478a-a3c4-b6431d71a9ca

The open-access MAF lists 193 somatic variants for this specimen: 139 protein-altering or splice-affecting, 45 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 45, Nonsense Mutation 8, Intron 5, Splice Region 5, Frame Shift Del 4, 5'Flank 2, 5'UTR 2, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 88/191 reads (46%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 449/671 reads (67%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 170/350 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSBG1 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 163/381 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs774668709, COSV51906562; called by muse, mutect2, varscan2
- ADAMTS7 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 224/483 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs758723833; called by muse, mutect2, varscan2
- ADGRL1 | c.2387A>G p.N796S (on ENST00000340736 / NM_001008701.3; = p.N791S on NM_014921.5) | Missense Mutation (SNP) | VAF 126/239 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs757599356; called by muse, mutect2
- ADRA1D | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 264/397 reads (66%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1015715330; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2972C>T p.T991M | Missense Mutation (SNP) | VAF 140/311 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs377446677; called by muse, mutect2, varscan2
- APEX1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 154/303 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752473392, COSV99032172; called by muse, mutect2, varscan2
- ASIC4 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 242/533 reads (45%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.776); catalogued as rs770046746; called by muse, mutect2, varscan2
- ASPM | c.5186G>A p.R1729Q | Missense Mutation (SNP) | VAF 174/736 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.227); catalogued as rs768999000, COSV54128816, COSV54128933; called by muse, mutect2, varscan2
- B3GALT1 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 217/424 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as rs150305076; called by muse, mutect2, varscan2
- BPIFC | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 164/366 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs78469100, COSV55910676; called by muse, mutect2, varscan2
- CD1E | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 184/883 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100937010, COSV63770217; called by muse, mutect2, varscan2
- CELSR3 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 282/593 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1372477014, COSV50902205, COSV99375140; called by muse, mutect2, varscan2
- CFAP99 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 140/322 reads (43%) | catalogued as rs537841039; called by muse, mutect2, varscan2
- CHST9 | c.986A>G p.K329R | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV52434844, COSV99410344; called by muse, mutect2, varscan2
- COA5 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 111/230 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs376113873; called by muse, mutect2, varscan2
- DNAJC6 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 141/331 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs549580287; called by muse, mutect2, varscan2
- DRC1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs1311428069; called by muse, mutect2, varscan2
- EEA1 | c.1079T>A p.L360Q | Missense Mutation (SNP) | VAF 110/239 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1414802587; called by muse, mutect2, varscan2
- EFNA2 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 338/691 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as rs763961946; called by muse, mutect2, varscan2
- ERN1 | c.2605G>A p.V869M | Missense Mutation (SNP) | VAF 168/372 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778413463; called by muse, mutect2, varscan2
- FAM53B | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 148/349 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1410825842; called by muse, mutect2, varscan2
- FPR2 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 64/564 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV60673087; called by muse, mutect2, varscan2
- GABRA5 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 106/224 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs1274121828, COSV104409320; called by muse, mutect2, varscan2
- GRAP2 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 270/550 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777566631, COSV59995855; called by muse, varscan2
- GRM6 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 112/225 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as rs774644036, COSV51436399; called by muse, mutect2, varscan2
- H3-5 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 287/557 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV100461701; called by muse, mutect2
- HACD3 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 118/248 reads (48%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.787); catalogued as COSV99971273; called by muse, mutect2, varscan2
- HECW1 | c.4690A>G p.K1564E | Missense Mutation (SNP) | VAF 150/455 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.23); catalogued as rs1279263202; called by muse, mutect2, varscan2
- HERC2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 273/551 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.08); catalogued as rs772532798; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPB2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 303/599 reads (51%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.541); catalogued as rs1555165860, COSV57051679; called by muse, mutect2, varscan2
- IGF2BP1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 254/475 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.662); catalogued as COSV51731837; called by muse, mutect2, varscan2
- KCNG2 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 304/638 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs544952689; called by muse, mutect2, varscan2
- KIF13B | c.3275G>T p.R1092L | Missense Mutation (SNP) | VAF 131/295 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV72954492; called by muse, mutect2, varscan2
- KRT82 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 222/434 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs113026141; called by muse, mutect2, varscan2
- LYST | c.2731A>G p.K911E | Missense Mutation (SNP) | VAF 27/850 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.773); catalogued as rs1031493476; called by muse, mutect2
- MAGI1 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 117/268 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as rs1188679788; called by muse, mutect2, varscan2
- MCMBP | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 145/344 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760211029; called by muse, mutect2, varscan2
- METAP1D | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 252/522 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs2120353; called by muse, mutect2, varscan2
- MOK | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 174/382 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs747272869, COSV99513778; called by muse, mutect2, varscan2
- MYH6 | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 159/351 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs576497958; called by muse, mutect2, varscan2
- NETO1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 168/358 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1204319408; called by muse, mutect2, varscan2
- NMBR | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 75/453 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as rs758523214; called by muse, mutect2, varscan2
- NRN1L | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 294/638 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as rs769584336; called by muse, mutect2, varscan2
- NSUN5 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 491/794 reads (62%) | catalogued as rs374889055; called by muse, mutect2, varscan2
- OCM | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 47/610 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772780728, COSV54194176; called by muse, mutect2
- OR2W3 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 503/684 reads (74%) | SIFT tolerated (0.52); PolyPhen benign (0.182); catalogued as rs369250388, COSV64456271; called by muse, mutect2, varscan2
- P2RX7 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 161/336 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs201451288; called by muse, mutect2, varscan2
- PCDHGA8 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 151/343 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV53986400; called by muse, mutect2, varscan2
- PDE7B | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 103/320 reads (32%) | catalogued as rs193920799, COSV57492185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEBP1 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs745741685; called by muse, mutect2, varscan2
- PGS1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 183/357 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs749520109; called by muse, mutect2, varscan2
- ROR1 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 182/350 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.21); catalogued as rs371110337; called by muse, mutect2, varscan2
- SH3RF3 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 67/551 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs368451676; called by muse, mutect2, varscan2
- SHANK1 | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 347/710 reads (49%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV53259143; called by muse, mutect2, varscan2
- SIPA1L2 | c.4195G>A p.G1399S | Missense Mutation (SNP) | VAF 558/766 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs200136990; called by muse, mutect2, varscan2
- SLC26A9 | c.951C>T p.R317= | Splice Region (SNP) | VAF 157/726 reads (22%) | catalogued as rs760498151, COSV61602677; called by muse, mutect2, varscan2
- SLC38A2 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 140/342 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1464532773, COSV56744065; called by muse, mutect2, varscan2
- SLC38A6 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555358125; called by muse, mutect2, varscan2
- SLC7A2 | c.1621G>A p.V541I (on ENST00000494857 / NM_001370338.1; = p.V580I on NM_003046.6) | Missense Mutation (SNP) | VAF 213/448 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs368801565; called by muse, mutect2
- SMTNL2 | c.1373G>A p.R458H (on ENST00000389313 / NM_001114974.2; = p.R314H on NM_198501.3) | Missense Mutation (SNP) | VAF 140/298 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1300405248; called by muse, mutect2, varscan2
- STAT3 | c.1599G>A p.L533= | Splice Region (SNP) | VAF 137/272 reads (50%) | catalogued as COSV99233056; called by muse, mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 124/243 reads (51%) | catalogued as rs745872748; called by mutect2, varscan2
- TGIF1 | c.183G>A p.Q61= (on ENST00000330513 / NM_001374396.1; = p.Q81= on NM_003244.4) | Splice Region (SNP) | VAF 237/483 reads (49%) | catalogued as COSV57909842; called by muse, mutect2, varscan2
- TMEM132E | c.2480G>A p.R827Q (on ENST00000321639; = p.R917Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 297/643 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs757230221; called by muse, mutect2, varscan2
- TTN | c.28193C>T p.A9398V (on ENST00000591111; = p.A8471V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/258 reads (46%) | PolyPhen benign (0.425); catalogued as rs533172128, COSV60211703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VANGL1 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 110/246 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs371428273; called by muse, mutect2, varscan2
- WDR90 | c.2060C>T p.T687M | Missense Mutation (SNP) | VAF 256/535 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs756640844; called by muse, mutect2, varscan2
- WFS1 | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 311/597 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.906); catalogued as rs143055296, CM1515115, COSV99901167; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WRAP53 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 251/515 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs35123152; called by muse, mutect2, varscan2
- ZFHX4 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 119/268 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV50496590, COSV51487275; called by muse, mutect2, varscan2
- ZNF467 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 303/911 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1305334072; called by muse, mutect2, varscan2
- ZNF92 | c.594G>C p.E198D (on ENST00000328747 / NM_152626.4; = p.E129D on NM_007139.4) | Missense Mutation (SNP) | VAF 87/294 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.384); catalogued as COSV60875717; called by muse, mutect2, varscan2
- ABCC4 | c.983G>C p.S328T | Missense Mutation (SNP) | VAF 148/475 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADAMTS13 | c.849G>T p.W283C | Missense Mutation (SNP) | VAF 48/1006 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); called by muse, mutect2
- ALOX5 | c.401A>C p.K134T | Missense Mutation (SNP) | VAF 215/454 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- APC | c.4473del p.F1491Lfs*16 | Frame Shift Del (DEL) | VAF 212/511 reads (41%) | called by mutect2, pindel, varscan2
- ATP1B1 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 186/743 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCL9L | c.2900C>A p.A967D | Missense Mutation (SNP) | VAF 250/536 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- C8orf82 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 251/587 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- C8orf82 | c.612G>C p.M204I | Missense Mutation (SNP) | VAF 252/591 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C9 | c.1355T>A p.V452E | Missense Mutation (SNP) | VAF 189/396 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CD2 | c.233T>G p.F78C | Missense Mutation (SNP) | VAF 132/286 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- CDX2 | c.630C>A p.Y210* | Nonsense Mutation (SNP) | VAF 203/623 reads (33%) | called by muse, mutect2, varscan2
- CFAP43 | c.4242G>T p.E1414D | Missense Mutation (SNP) | VAF 131/274 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CHRM4 | c.404C>A p.T135N | Missense Mutation (SNP) | VAF 50/468 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CHST12 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 250/756 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COCH | c.876T>A p.D292E (on ENST00000216361 / NM_001347720.1; = p.D227E on NM_004086.3) | Missense Mutation (SNP) | VAF 155/301 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- COL22A1 | c.1184A>T p.N395I | Missense Mutation (SNP) | VAF 198/384 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DMD | c.4030C>A p.L1344I | Missense Mutation (SNP) | VAF 202/203 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- DMTF1 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 225/651 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- DNAH14 | c.1303C>T p.Q435* (on ENST00000445597; = p.Q416* on NM_001145154.3) | Nonsense Mutation (SNP) | VAF 187/757 reads (25%) | called by muse, mutect2, varscan2
- DOCK3 | c.4799A>G p.H1600R | Missense Mutation (SNP) | VAF 199/373 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- DYNC1H1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 166/318 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EDEM2 | c.1236A>T p.T412= | Splice Region (SNP) | VAF 104/288 reads (36%) | called by muse, mutect2, varscan2
- EPHA6 | c.3025_3027del p.K1009del | In Frame Del (DEL) | VAF 43/368 reads (12%) | called by mutect2, pindel, varscan2
- EXOC1 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 123/273 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- FBN3 | c.5489G>A p.C1830Y | Missense Mutation (SNP) | VAF 172/392 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- FKBP1B | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 166/329 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FRMD4B | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 128/293 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GPCPD1 | c.690C>G p.I230M | Missense Mutation (SNP) | VAF 114/349 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HIRA | c.2032G>T p.A678S | Missense Mutation (SNP) | VAF 56/393 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN1 | c.5263G>T p.D1755Y | Missense Mutation (SNP) | VAF 101/505 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- IARS1 | c.2566G>A p.D856N | Missense Mutation (SNP) | VAF 228/384 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- KALRN | c.1948_1949dup p.K651Pfs*30 | Frame Shift Ins (INS) | VAF 108/230 reads (47%) | called by mutect2, varscan2
- KIF4B | c.3045C>G p.D1015E | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.942); called by muse, mutect2
- LHX1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 222/497 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- LRRC37B | c.1380G>T p.E460D | Missense Mutation (SNP) | VAF 115/295 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MAP3K5 | c.2168A>C p.H723P | Missense Mutation (SNP) | VAF 85/223 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- MPC1L | c.112_122del p.L38Cfs*3 | Frame Shift Del (DEL) | VAF 55/261 reads (21%) | called by mutect2, pindel, varscan2
- MSH4 | c.2023T>C p.F675L | Missense Mutation (SNP) | VAF 99/254 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- NRXN1 | c.212A>C p.D71A | Missense Mutation (SNP) | VAF 296/572 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- OR4K14 | c.79T>A p.F27I | Missense Mutation (SNP) | VAF 130/284 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- OR6Q1 | c.530T>G p.V177G | Missense Mutation (SNP) | VAF 236/456 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- OTUD6B | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 46/466 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAPPA2 | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 655/886 reads (74%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PLXND1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 70/802 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRR30 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 259/540 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PYM1 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 210/468 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- RAG1 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 25/452 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- RIMS2 | c.2723A>C p.D908A (on ENST00000666250 / NM_001348490.2; = p.D716A on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/197 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RPA1 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 22/419 reads (5%) | called by muse, mutect2
- SLC37A4 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 173/358 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX8 | c.918T>C p.G306= | Splice Region (SNP) | VAF 50/698 reads (7%) | called by muse, mutect2
- SRRD | c.683A>G p.N228S | Missense Mutation (SNP) | VAF 205/409 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- THEGL | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 225/467 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- TLE2 | c.746G>T p.S249I | Missense Mutation (SNP) | VAF 18/528 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TMEM67 | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TPP1 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 48/586 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.477); called by muse, mutect2
- TRIM77 | c.167G>T p.R56M | Missense Mutation (SNP) | VAF 203/433 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- TTLL2 | c.561C>G p.D187E | Missense Mutation (SNP) | VAF 25/419 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.349); called by muse, mutect2
- TWIST1 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 171/523 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- UBR1 | c.1678_1679del p.L560Tfs*5 | Frame Shift Del (DEL) | VAF 83/225 reads (37%) | called by mutect2, pindel, varscan2
- UNC13A | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 241/521 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- WWC1 | c.2001-1G>C p.X667_splice | Splice Site (SNP) | VAF 123/249 reads (49%) | called by muse, mutect2, varscan2
- ZBTB4 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 180/573 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF225 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AAK1 | c.2055C>T p.N685= | Silent (SNP) | VAF 108/270 reads (40%) | catalogued as rs371548831; called by muse, mutect2, varscan2
- AOAH | c.1680G>A p.P560= | Silent (SNP) | VAF 201/624 reads (32%) | called by muse, mutect2, varscan2
- ARAP2 | c.1017C>G p.L339= | Silent (SNP) | VAF 73/158 reads (46%) | catalogued as COSV58293654; called by muse, mutect2, varscan2
- ATP2B2 | c.1023C>T p.D341= (on ENST00000352432; = p.D307= on NM_001683.5) | Silent (SNP) | VAF 153/329 reads (47%) | catalogued as rs369726075, COSV59504958; called by muse, mutect2, varscan2
- CACNA1B | c.5145G>A p.T1715= | Silent (SNP) | VAF 170/501 reads (34%) | catalogued as rs1230477201, COSV53112391; called by muse, mutect2, varscan2
- CD93 | c.1047C>T p.C349= | Silent (SNP) | VAF 268/817 reads (33%) | called by muse, mutect2, varscan2
- CHRM4 | c.405C>A p.T135= | Silent (SNP) | VAF 50/468 reads (11%) | called by muse, mutect2, varscan2
- CTNNA3 | c.114A>G p.V38= | Silent (SNP) | VAF 93/190 reads (49%) | called by muse, mutect2, varscan2
- DDR2 | c.471G>T p.P157= | Silent (SNP) | VAF 540/754 reads (72%) | catalogued as rs374094270; called by muse, mutect2, varscan2
- DLGAP1 | c.513C>T p.D171= | Silent (SNP) | VAF 336/687 reads (49%) | catalogued as COSV59782356; called by muse, mutect2, varscan2
- DOCK3 | c.4185G>A p.P1395= | Silent (SNP) | VAF 211/484 reads (44%) | catalogued as rs367930026; called by muse, mutect2, varscan2
- ECE1 | c.2031G>A p.A677= | Silent (SNP) | VAF 143/327 reads (44%) | catalogued as rs764345139; called by muse, mutect2, varscan2
- FRAS1 | c.2856C>T p.T952= | Silent (SNP) | VAF 134/273 reads (49%) | called by muse, mutect2, varscan2
- FZD8 | c.1536G>A p.S512= | Silent (SNP) | VAF 207/429 reads (48%) | catalogued as rs1290191206, COSV65967526; called by muse, mutect2, varscan2
- GRAMD4 | c.1038C>T p.F346= | Silent (SNP) | VAF 215/416 reads (52%) | catalogued as rs1054130178; called by muse, mutect2, varscan2
- HPS6 | c.354C>T p.T118= | Silent (SNP) | VAF 440/921 reads (48%) | catalogued as rs1288379163; called by muse, mutect2, varscan2
- IGF1R | c.3672C>T p.F1224= | Silent (SNP) | VAF 225/470 reads (48%) | catalogued as rs764671728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITIH5 | c.912T>G p.A304= | Silent (SNP) | VAF 137/273 reads (50%) | catalogued as COSV53663070; called by muse, mutect2, varscan2
- KCNQ2 | c.2331C>T p.P777= (on ENST00000359125 / NM_172107.4; = p.P749= on NM_004518.6) | Silent (SNP) | VAF 587/906 reads (65%) | catalogued as rs903555499, COSV60545621; ClinVar: likely benign; called by muse, mutect2, varscan2
- MEGF11 | c.3114G>A p.P1038= | Silent (SNP) | VAF 131/279 reads (47%) | catalogued as rs377174263; called by muse, mutect2, varscan2
- NKX1-1 | c.648C>T p.G216= | Silent (SNP) | VAF 84/759 reads (11%) | called by muse, mutect2, varscan2
- NTN5 | c.558C>T p.C186= | Silent (SNP) | VAF 353/671 reads (53%) | catalogued as rs1241022978; called by muse, mutect2, varscan2
- OR2T1 | c.348C>T p.L116= | Silent (SNP) | VAF 359/1402 reads (26%) | catalogued as COSV63542385; called by muse, mutect2, varscan2
- OR52N2 | c.123C>T p.V41= | Silent (SNP) | VAF 193/420 reads (46%) | catalogued as rs112125234, COSV100396225; called by muse, mutect2, varscan2
- PCDHA10 | c.1440C>T p.D480= | Silent (SNP) | VAF 337/709 reads (48%) | catalogued as COSV56500259; called by muse, mutect2, varscan2
- PCDHB10 | c.1788G>A p.S596= | Silent (SNP) | VAF 203/665 reads (31%) | catalogued as rs1554284381; called by muse, mutect2, varscan2
- PCDHB5 | c.1662C>T p.N554= | Silent (SNP) | VAF 388/852 reads (46%) | catalogued as rs368703808; called by muse, mutect2, varscan2
- PEX6 | c.2181C>T p.H727= | Silent (SNP) | VAF 387/482 reads (80%) | called by muse, mutect2, varscan2
- PLCE1 | c.3837G>A p.S1279= | Silent (SNP) | VAF 97/201 reads (48%) | catalogued as rs754326671; called by muse, mutect2, varscan2
- PRDX2 | c.372T>C p.I124= | Silent (SNP) | VAF 93/229 reads (41%) | called by muse, mutect2, varscan2
- PRRT3 | c.1686G>C p.A562= | Silent (SNP) | VAF 288/590 reads (49%) | catalogued as rs758306980; called by muse, mutect2, varscan2
- RASGRF1 | c.264G>A p.P88= | Silent (SNP) | VAF 210/461 reads (46%) | catalogued as rs1335518170, COSV69181523; called by muse, mutect2, varscan2
- RGMA | c.267G>A p.T89= | Silent (SNP) | VAF 266/603 reads (44%) | catalogued as rs557195147; called by muse, mutect2, varscan2
- ROR1 | c.2490G>A p.A830= | Silent (SNP) | VAF 201/470 reads (43%) | catalogued as rs146764088; called by muse, mutect2, varscan2
- SHISA7 | c.1572G>A p.L524= | Silent (SNP) | VAF 191/447 reads (43%) | called by muse, mutect2, varscan2
- SHROOM2 | c.4434C>T p.G1478= | Silent (SNP) | VAF 394/395 reads (100%) | catalogued as rs1010949429; called by muse, mutect2, varscan2
- SIK2 | c.2250G>A p.Q750= | Silent (SNP) | VAF 244/542 reads (45%) | called by muse, mutect2, varscan2
- SLC16A5 | c.525C>T p.F175= | Silent (SNP) | VAF 253/545 reads (46%) | catalogued as rs761950014; called by muse, mutect2, varscan2
- STARD10 | c.759G>A p.S253= | Silent (SNP) | VAF 251/551 reads (46%) | catalogued as rs895513563; called by muse, mutect2, varscan2
- SYNPO | c.2226T>G p.S742= (on ENST00000394243 / NM_001166208.2; = p.S498= on NM_007286.6) | Silent (SNP) | VAF 310/599 reads (52%) | called by muse, mutect2, varscan2
- TLL2 | c.498C>T p.Y166= | Silent (SNP) | VAF 113/272 reads (42%) | catalogued as rs763235245, COSV63573574; called by muse, mutect2, varscan2
- TRPV2 | c.1647C>T p.F549= | Silent (SNP) | VAF 159/348 reads (46%) | catalogued as rs751435857; called by muse, mutect2, varscan2
- TTN | c.26742C>T p.T8914= (on ENST00000591111; = p.T7987= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/413 reads (12%) | catalogued as rs752794790; called by muse, mutect2, varscan2
- UROC1 | c.747C>T p.L249= | Silent (SNP) | VAF 306/628 reads (49%) | catalogued as rs766972220, COSV52035114; called by muse, mutect2, varscan2
- USP17L1 | c.276C>T p.N92= | Silent (SNP) | VAF 80/306 reads (26%) | catalogued as rs750022874; called by muse, varscan2
- CCN6 | c.-23-22C>T | Intron (SNP) | VAF 15/368 reads (4%) | catalogued as rs373922145; called by muse, mutect2
- DUSP22 | c.508+36C>T | Intron (SNP) | VAF 44/325 reads (14%) | catalogued as rs1194398045, COSV100739571; called by muse, mutect2, varscan2
- FRRS1L | c.-100G>T | 5'UTR (SNP) | VAF 280/806 reads (35%) | called by muse, mutect2, varscan2
- NACA | c.70+3964del | Intron (DEL) | VAF 182/435 reads (42%) | called by mutect2, pindel, varscan2
- NRG1 | chr8:31640176 G>A | 5'Flank (SNP) | VAF 220/482 reads (46%) | called by muse, varscan2
- PLA2G6 | c.210-2913C>T | Intron (SNP) | VAF 199/385 reads (52%) | catalogued as rs1006747639; called by muse, mutect2, varscan2
- PLCH2 | c.2959+420G>C | Intron (SNP) | VAF 290/628 reads (46%) | called by muse, mutect2, varscan2
- SERPINA9 | c.-14T>G | 5'UTR (SNP) | VAF 122/228 reads (54%) | called by muse, mutect2, varscan2
- TLE5 | chr19:3062850 G>T | 5'Flank (SNP) | VAF 242/514 reads (47%) | called by muse, mutect2, varscan2
